CPTAC case C3N-03449 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a5d05493-9f75-4207-8be0-49a876c31ab7

Demographics
Sex at birth: male; Race: white; Year of birth: 1958; Vital status: Dead; Days to death: 179 days; Year of death: 2018; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 59.6 years (21,763 days); Year of diagnosis: 2017; Last known disease status: With tumor; Days to last known disease status: 179 days; Progression or recurrence: yes; Days to recurrence: 175 days; Days to last follow up: 179 days.
   Pathology details: Greatest tumor dimension: 5.9 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (1 entry)
- Days to follow up: 179 days; Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 175 days; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 74 kg; Height: 171 cm; BMI: 25.31.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03449-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -22 days; Initial weight: 207 mg; Time between excision and freezing: 12 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03449-21: Section location: Right Hemisphere; Percent tumor nuclei: 90; Percent necrosis: 3.
- Sample C3N-03449-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -22 days; Method of sample procurement: Blood Draw.
